TCGA case TCGA-95-7562 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Washington University - Emory. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/193201a3-1447-47b1-bdf1-11ae0eb3b2f3

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 71 years; Vital status: Dead; Days to death: 87 days.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 71.2 years (26,000 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed Disodium; Days to treatment start: 60 days; Days to treatment end: 81 days; Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the prostate gland (histology not recorded by GDC).
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 87 days; Disease response: Tumor Free.
- ECOG performance status: 1; Timepoint: Post Adjuvant Therapy.

Other clinical attributes
- DLCO (% of predicted): 57; FEV1/FVC after bronchodilator (%): 72; FEV1/FVC before bronchodilator (%): 76; FEV1 after bronchodilator (% of reference): 90; FEV1 before bronchodilator (% of reference): 80.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 10; Tobacco smoking onset year: 1973; Tobacco smoking quit year: 1983.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-95-7562-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.5; Shortest dimension: 0.2.
  Slide TCGA-95-7562-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 5.
- Sample TCGA-95-7562-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-95-7562-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Performance status timing: Post-Adjuvant Therapy; Tobacco smoking history indicator: 3; Anatomic organ subdivision: R-Lower; Pulmonary function test indicator: Yes; New tumor event diagnosis indicator: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Alimta.
- Follow-up form: Lost to follow-up: No; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Performance status timing: Post-Adjuvant Therapy.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No.

GDC annotations on this case (curator notes; quoted as recorded):
- History of acceptable prior treatment related to a prior/other malignancy: Prior malignancy prostate cancer treated with locoregional radiation.
- Prior malignancy: Prior malignancy prostate cancer treated with locoregional radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 87 days; disease-specific survival: no event (censored), 87 days; progression-free interval: no event (censored), 87 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-95-7562-01A-11D-2237-01): tumor purity 0.55, ploidy 3.68, whole-genome doublings 2.
